Somatic mutation profile of tumor specimen TCGA-CN-6988-01A (aliquot TCGA-CN-6988-01A-11D-1912-08) from TCGA case TCGA-CN-6988, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 47.4 years (17,308 days).
Specimen TCGA-CN-6988-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95f181f7-3972-4aef-beba-52c65f57cbc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6988-10A (Blood Derived Normal), aliquot TCGA-CN-6988-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2f940c9-2f05-4731-b4d8-a57ed46b400e

The open-access MAF lists 168 somatic variants for this specimen: 123 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 40, Intron 4, Nonsense Mutation 4, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 2, 5'UTR 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99714101; called by muse, mutect2, varscan2
- ADAM11 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs748075525, COSV99567768; called by muse, mutect2, varscan2
- ADGRL3 | c.2542C>G p.P848A (on ENST00000506720 / NM_001322402.2; = p.P780A on NM_015236.6) | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.029); catalogued as COSV101547368; called by muse, mutect2, varscan2
- AFF2 | c.3162C>A p.S1054R | Missense Mutation (SNP) | VAF 145/167 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV99665861; called by muse, mutect2, varscan2
- AMBRA1 | c.3010G>T p.D1004Y (on ENST00000458649 / NM_001367468.1; = p.D914Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100095151; called by muse, mutect2, varscan2
- ANK2 | c.8113C>T p.P2705S | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100003734; called by muse, mutect2, varscan2
- ANXA7 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.932); catalogued as COSV100873498; called by muse, mutect2, varscan2
- AOX1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.068); catalogued as COSV101022203; called by muse, mutect2, varscan2
- AQP6 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100210264, COSV59646898; called by muse, varscan2
- AURKC | c.749G>T p.R250L (on ENST00000302804 / NM_001015878.2; = p.R216L on NM_003160.3) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV100248977; called by muse, mutect2, varscan2
- C1S | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV100196760; called by muse, mutect2, varscan2
- CCDC27 | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99622845; called by muse, mutect2, varscan2
- CDH11 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747102834, COSV51774410, COSV51776848, COSV99219561; called by muse, mutect2, varscan2
- CDH6 | c.2089C>A p.L697I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as COSV54065505, COSV99420579; called by muse, mutect2, varscan2
- CDH9 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs201758024, COSV99151406, COSV99153292; called by muse, mutect2, varscan2
- CECR2 | c.3308G>C p.R1103T (on ENST00000342247 / NM_001290047.2; = p.R919T on NM_001290046.1) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.212); catalogued as COSV99378931; called by muse, mutect2, varscan2
- CFAP46 | c.7448A>G p.E2483G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99585423; called by muse, mutect2, varscan2
- CHD7 | c.5725C>A p.L1909M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV101418063; called by muse, varscan2
- COL24A1 | c.4810A>G p.M1604V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100993905; called by muse, mutect2, varscan2
- COLEC11 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1360887774, COSV52595288; called by muse, mutect2, varscan2
- CSN2 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100778821, COSV61992322; called by muse, mutect2, varscan2
- CSTL1 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99851071; called by muse, mutect2, varscan2
- CYTL1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV100312509; called by mutect2, varscan2
- DCTN1 | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV100721049; called by muse, mutect2, varscan2
- DDHD2 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV101240765; called by muse, mutect2, varscan2
- DNAH17 | c.573C>G p.H191Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV67756473; called by muse, mutect2, varscan2
- DOCK2 | c.3324A>G p.I1108M | Missense Mutation (SNP) | VAF 124/172 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99914734; called by muse, mutect2, varscan2
- DPP6 | c.1866C>A p.Y622* (on ENST00000377770 / NM_001364500.2; = p.Y560* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as rs907617235, COSV100127694; called by muse, mutect2, varscan2
- DYNLL1 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs748141393, COSV99655576; called by muse, mutect2, varscan2
- EPB41L2 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100441311; called by muse, mutect2, varscan2
- ERBB4 | c.1585G>T p.G529* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs746277222, COSV99631078; called by muse, mutect2, varscan2
- FCGR3A | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100914700; called by muse, varscan2
- FER | c.2446A>G p.I816V | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99813770; called by muse, mutect2, varscan2
- FRZB | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.187); catalogued as COSV99717520; called by muse, mutect2, varscan2
- GABRB3 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100161433; called by muse, mutect2, varscan2
- GRID2 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV99945622; called by muse, mutect2, varscan2
- GRM5 | c.954G>T p.Q318H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100554087; called by muse, mutect2, varscan2
- HDAC7 | c.379C>T p.R127C (on ENST00000427332; = p.R166C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.409); catalogued as rs773040801, COSV99316828; called by muse, mutect2, varscan2
- HDHD2 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100321395; called by muse, mutect2, varscan2
- HEBP2 | c.587A>C p.Q196P | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV100874953; called by muse, mutect2, varscan2
- HERC1 | c.9535G>A p.A3179T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101496838; called by muse, mutect2, varscan2
- HIVEP2 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.777); catalogued as COSV50009097, COSV99175099; called by muse, mutect2, varscan2
- IQSEC3 | c.2194G>A p.D732N (on ENST00000538872 / NM_001170738.2; = p.D429N on NM_015232.1) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100407544; called by muse, mutect2, varscan2
- ITGA1 | c.1904A>T p.Q635L | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99252010; called by muse, mutect2, varscan2
- KCNK16 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV100949296; called by muse, mutect2
- KPNA3 | c.727-1G>C p.X243_splice | Splice Site (SNP) | VAF 18/23 reads (78%) | catalogued as COSV99904338; called by muse, mutect2, varscan2
- KRTAP13-4 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 40/66 reads (61%) | catalogued as COSV100481823; called by muse, mutect2, varscan2
- LAMA2 | c.4490G>A p.C1497Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370774; called by muse, mutect2, varscan2
- LRRTM4 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775060136, COSV69140107, COSV69141445; called by muse, mutect2, varscan2
- MED13 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV63228757; called by muse, mutect2, varscan2
- MEF2C | c.1124C>G p.S375C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100426093; called by muse, mutect2
- MOXD1 | c.1587G>C p.W529C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381299, COSV100381837; called by muse, mutect2, varscan2
- MTF2 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100940174; called by muse, mutect2, varscan2
- MTMR2 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100656825; called by muse, mutect2, varscan2
- MYH15 | c.896T>A p.F299Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV99844128; called by muse, mutect2, varscan2
- MYO16 | c.1079A>C p.K360T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99194475; called by muse, mutect2, varscan2
- MYO1E | c.3032C>T p.T1011M | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs546147455, COSV99896459; called by muse, mutect2, varscan2
- NAALADL2 | c.280A>G p.K94E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV101435790; called by muse, mutect2, varscan2
- NIPBL | c.7204A>G p.N2402D | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV99242276; called by muse, mutect2, varscan2
- NLGN1 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 155/234 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV100849959; called by muse, mutect2, varscan2
- NME7 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100891142; called by muse, mutect2, varscan2
- NSMCE4A | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100940085; called by muse, mutect2, varscan2
- ONECUT1 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100009407; called by muse, mutect2, varscan2
- PCDH10 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99994338; called by muse, mutect2, varscan2
- PGLYRP4 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 108/189 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.112); catalogued as COSV100668504; called by muse, mutect2, varscan2
- PIP5K1A | c.762G>A p.M254I (on ENST00000368888 / NM_001135638.2; = p.M241I on NM_003557.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV100576740; called by muse, mutect2, varscan2
- PLOD2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99283213; called by muse, mutect2, varscan2
- PNLIPRP2 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.277); catalogued as COSV100077936, COSV53946190; called by muse, mutect2, varscan2
- POLG2 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99858221; called by muse, mutect2, varscan2
- POTEF | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV100665266; called by mutect2, varscan2
- PPP1R12A | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.426); catalogued as rs551709799, COSV99700756; called by muse, mutect2, varscan2
- PSMA8 | c.753dup p.S252Ifs*16 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs777177735; called by mutect2, pindel, varscan2
- PTPN12 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99950650; called by muse, mutect2, varscan2
- RAD51C | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99543333; called by muse, mutect2, varscan2
- RASGRF2 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV99430090; called by muse, mutect2, varscan2
- RC3H1 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | catalogued as COSV99281689, COSV99281711; called by muse, mutect2, varscan2
- RECQL5 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778590962, COSV100512285; called by muse, mutect2, varscan2
- REG1B | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV59308084; called by muse, mutect2, varscan2
- RELN | c.4466G>T p.G1489V | Missense Mutation (SNP) | VAF 694/854 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100634653, COSV59016939; called by muse, mutect2, varscan2
- REV3L | c.5989T>A p.C1997S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100725613; called by muse, mutect2, varscan2
- RYR1 | c.5631G>T p.E1877D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.258); catalogued as COSV62088567; called by muse, mutect2, varscan2
- RYR2 | c.526C>G p.R176G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100772411, COSV63659100; called by muse, mutect2, varscan2
- SCN10A | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101479508; called by muse, mutect2, varscan2
- SH3BP4 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60644614; called by muse, mutect2, varscan2
- SH3BP4 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365950929, COSV100749284; called by muse, mutect2, varscan2
- SI | c.3995C>T p.A1332V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs747041492, COSV100016853, COSV100016928; called by muse, mutect2, varscan2
- SLC16A1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs774823539, COSV63709858; called by muse, mutect2, varscan2
- SLC35D1 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV99338475; called by muse, mutect2, varscan2
- SLC6A2 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99574465; called by muse, mutect2, varscan2
- SLCO1B1 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778090777, COSV57012843; called by muse, mutect2, varscan2
- SMCHD1 | c.2011A>G p.R671G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99862390; called by muse, mutect2
- SORL1 | c.3685G>T p.D1229Y | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99495214; called by muse, mutect2, varscan2
- STK36 | c.1490G>C p.R497P | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV99831863; called by muse, mutect2, varscan2
- TDRD7 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100795776; called by muse, mutect2, varscan2
- TDRD7 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100795777; called by muse, mutect2, varscan2
- TMEM132E | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1261443520, COSV100396711; called by muse, mutect2, varscan2
- TMEM200A | c.1091C>G p.A364G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV99759884; called by muse, mutect2, varscan2
- TNFRSF11A | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1161044137, COSV99500532; called by muse, mutect2, varscan2
- TNIK | c.3808C>T p.R1270W | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754276249, COSV52683398; called by muse, mutect2, varscan2
- TOX2 | c.1278G>T p.M426I (on ENST00000358131 / NM_001098798.2; = p.M402I on NM_032883.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as COSV100364534, COSV57889415; called by muse, mutect2, varscan2
- TRIM35 | c.965C>G p.T322S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.426); catalogued as rs935291269, COSV100542850; called by muse, mutect2, varscan2
- TRRAP | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); catalogued as COSV100722836; called by muse, mutect2, varscan2
- TTN | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | PolyPhen probably damaging (0.996); catalogued as rs151174349; called by muse, mutect2, varscan2
- UBR5 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.29); catalogued as COSV99642105; called by muse, mutect2, varscan2
- UBXN2B | c.733A>C p.N245H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs768853683, COSV101275616; called by muse, mutect2, varscan2
- UGT2B28 | c.1091-1G>A p.X364_splice | Splice Site (SNP) | VAF 36/99 reads (36%) | catalogued as COSV100159011; called by muse, mutect2
- UNC5C | c.1915G>T p.V639F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101498009; called by muse, mutect2, varscan2
- USP26 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100896740, COSV63708155; called by muse, mutect2, varscan2
- VPS39 | c.1063A>C p.N355H (on ENST00000348544 / NM_001301138.2; = p.N344H on NM_015289.5) | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as rs777472248, COSV100529510; called by muse, mutect2, varscan2
- WSCD2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54588323; called by muse, mutect2, varscan2
- ZEB2 | c.3149C>G p.S1050W | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100356710; called by muse, mutect2
- ZNF418 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs1450944955, COSV101268987; called by muse, mutect2, varscan2
- ZNF502 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as rs1231553352, COSV99939846; called by muse, mutect2, varscan2
- ZNF582 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100018896; called by muse, mutect2, varscan2
- ZNF608 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV100102320; called by muse, mutect2, varscan2
- ZNF667 | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52639738; called by muse, mutect2, varscan2
- ATP1A3 | c.305dup p.F103Lfs*29 (on ENST00000545399 / NM_001256214.2; = p.F90Lfs*29 on NM_152296.5) | Frame Shift Ins (INS) | VAF 82/168 reads (49%) | called by mutect2, pindel, varscan2
- C12orf42 | c.1002del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel, varscan2
- EBF2 | c.1092_1098+4del p.X364_splice | Splice Site (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- MPP5 | c.1348dup p.Y450Lfs*2 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- MTUS1 | c.1886_1897del p.S629_A632del | In Frame Del (DEL) | VAF 28/116 reads (24%) | called by mutect2, pindel, varscan2
- PPP2R1B | c.147_149dup p.I50dup | In Frame Ins (INS) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- TP53 | c.415_425del p.K139Cfs*6 | Frame Shift Del (DEL) | VAF 33/43 reads (77%) | called by mutect2, pindel, varscan2
- A1CF | c.930T>A p.V310= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99257438; called by muse, mutect2, varscan2
- ABCA3 | c.2670G>A p.E890= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs772204940, COSV100069030; called by muse, varscan2
- ADAMTS18 | c.3066C>G p.A1022= | Silent (SNP) | VAF 51/94 reads (54%) | catalogued as COSV99273908; called by muse, mutect2, varscan2
- ADGRF5 | c.795C>A p.S265= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs776652561, COSV51929606, COSV99346283; called by muse, mutect2, varscan2
- ANO5 | c.2397A>T p.R799= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100202137; called by muse, mutect2, varscan2
- ATF6 | c.27C>A p.G9= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100909431; called by muse, mutect2, varscan2
- C11orf68 | c.423C>T p.H141= (on ENST00000530188; = p.H182= on NM_031450.4) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV56989773; called by muse, mutect2, varscan2
- CHP1 | c.210C>T p.F70= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100587166; called by muse, mutect2, varscan2
- CR1 | c.3546C>A p.A1182= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV100887990; called by muse, mutect2, varscan2
- CSN2 | c.279C>A p.V93= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100778822; called by muse, mutect2, varscan2
- CUBN | c.1596T>G p.L532= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100913395; called by muse, mutect2, varscan2
- CYP1B1 | c.867C>T p.P289= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV99572814; called by muse, varscan2
- DNAI2 | c.114C>A p.A38= | Silent (SNP) | VAF 35/236 reads (15%) | catalogued as COSV100209740, COSV100210022; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1482C>A p.L494= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV100668811; called by muse, mutect2, varscan2
- EID2B | c.87C>T p.S29= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100411046; called by muse, mutect2, varscan2
- ELOC | c.240G>A p.K80= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1168987409, COSV99514084; called by mutect2, varscan2
- EMSY | c.2577C>T p.P859= | Silent (SNP) | VAF 98/186 reads (53%) | catalogued as COSV100595996; called by muse, mutect2, varscan2
- ERBB4 | c.3459T>G p.P1153= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV100726968; called by muse, mutect2, varscan2
- F13A1 | c.543G>A p.T181= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs747128938, COSV53553981; called by muse, mutect2, varscan2
- FOXJ3 | c.906A>C p.S302= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as COSV100692156; called by muse, mutect2, varscan2
- FRMPD4 | c.3714G>T p.P1238= | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as COSV101043853; called by muse, mutect2, varscan2
- GATA3 | c.708C>A p.P236= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs143582578, CD071352, COSV100651203, COSV60516101; called by muse, mutect2, varscan2
- GRIK5 | c.135C>T p.A45= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99491263; called by muse, mutect2, varscan2
- IGSF1 | c.3267G>C p.G1089= | Silent (SNP) | VAF 106/120 reads (88%) | catalogued as COSV100812278; called by muse, mutect2, varscan2
- LILRB5 | c.1092G>C p.P364= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV100300727, COSV60260114; called by muse, mutect2, varscan2
- LRRTM4 | c.1263A>G p.S421= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as COSV101297701; called by muse, mutect2, varscan2
- NPAS2 | c.2103G>A p.R701= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as COSV100176821; called by muse, mutect2, varscan2
- PALB2 | c.930T>C p.S310= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV99848912; called by muse, mutect2, varscan2
- PEG3 | c.126T>A p.S42= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99690147; called by muse, mutect2, varscan2
- SHLD1 | c.138G>A p.L46= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as COSV100290675; called by muse, mutect2, varscan2
- SLC2A3 | c.435C>T p.I145= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV99306883; called by muse, mutect2, varscan2
- SLC6A19 | c.642C>T p.R214= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs376080842; called by mutect2, varscan2
- SLCO3A1 | c.324G>T p.L108= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100575848, COSV59232223, COSV59232693; called by muse, mutect2, varscan2
- SMCHD1 | c.3324G>T p.L1108= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV99862391; called by muse, mutect2, varscan2
- STAT2 | c.1779C>T p.T593= | Silent (SNP) | VAF 56/115 reads (49%) | catalogued as COSV100029099; called by muse, mutect2, varscan2
- STOX2 | c.1962G>A p.K654= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1476012245, COSV100409125; called by muse, mutect2, varscan2
- SYNPO2 | c.2151A>T p.S717= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100206280; called by muse, mutect2, varscan2
- TET1 | c.3612T>C p.H1204= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101018810; called by muse, mutect2, varscan2
- TUBB4B | c.861C>T p.P287= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs772348490, COSV100457695, COSV100458146, COSV100458149; called by muse, mutect2, varscan2
- USP18 | c.507G>A p.T169= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as rs776090736, COSV99306114; called by muse, mutect2, varscan2
- NPHP4 | c.2611+561C>T | Intron (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- RUSC1 | c.-126C>T | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99430209; called by muse, mutect2, varscan2
- TRIM36 | c.64-7403C>T | Intron (SNP) | VAF 62/84 reads (74%) | catalogued as COSV99142602; called by muse, mutect2, varscan2
- TRPM3 | c.979+17778T>A | Intron (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100678471; called by muse, mutect2, varscan2
- TTN | c.34264+2706C>G | Intron (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100626567; called by muse, mutect2, varscan2
